CCDI case PBCPAY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/b880a2a5-4e1f-4f5a-b9e2-9872d0d2b346

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 8.5 years (3,097 days).

Biospecimens (3 samples)
- Sample 0DWNR3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DWNST, 0DWNTT (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
